Somatic mutation profile of tumor specimen TCGA-PL-A8LZ-01A (aliquot TCGA-PL-A8LZ-01A-31D-A36J-09) from TCGA case TCGA-PL-A8LZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 29.8 years (10,869 days).
Specimen TCGA-PL-A8LZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a0243b2-9148-4c68-b533-099ed1fb6ee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PL-A8LZ-10A (Blood Derived Normal), aliquot TCGA-PL-A8LZ-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/152927d4-038b-489a-8e66-060322b56272

The open-access MAF lists 88 somatic variants for this specimen: 72 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 15, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.398G>T p.R133L (on ENST00000326724 / NM_001080395.3; = p.R30L on NM_004920.2) | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100452773; called by muse, mutect2, varscan2
- ADAM29 | c.1526T>A p.F509Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822011; called by muse, mutect2
- ANKRD24 | c.1397A>G p.E466G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99517465; called by muse, mutect2, varscan2
- AOC1 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs766973083, COSV100710762; called by muse, mutect2, varscan2
- BATF | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV99708835; called by muse, mutect2, varscan2
- BEST2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); catalogued as rs1266898005, COSV99244396; called by muse, mutect2
- C1orf54 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs149781166; called by muse, mutect2, varscan2
- CCDC144A | c.587T>A p.V196D | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as COSV100138528; called by muse, mutect2, varscan2
- CERKL | c.746T>C p.L249S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.021); catalogued as COSV100183679; called by muse, mutect2, varscan2
- CHRD | c.841+2T>A p.X281_splice | Splice Site (SNP) | VAF 7/135 reads (5%) | catalogued as COSV99200413; called by muse, mutect2
- CMKLR1 | c.885C>A p.S295R (on ENST00000312143 / NM_001142344.2; = p.S293R on NM_004072.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV100379380; called by muse, varscan2
- CMPK1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100898564, COSV100898569; called by muse, mutect2
- COL6A3 | c.9088C>T p.Q3030* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99798191; called by muse, mutect2, varscan2
- DGKK | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65707592; called by muse, mutect2, varscan2
- DNAJC28 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100074703; called by muse, mutect2, varscan2
- DOP1A | c.5156T>G p.M1719R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99381846; called by muse, mutect2, varscan2
- FAM9A | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen possibly damaging (0.569); catalogued as rs138064338, COSV101121341; called by muse, mutect2, varscan2
- FDFT1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); catalogued as rs556051417, COSV55044630; called by muse, mutect2
- FLYWCH1 | c.1780C>A p.P594T (on ENST00000253928 / NM_001308068.2; = p.P593T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1285540530, COSV99558863; called by muse, mutect2, varscan2
- FREM1 | c.5687C>A p.P1896H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101084482; called by muse, mutect2
- GIMAP8 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs1181536393, COSV100217525; called by muse, mutect2, varscan2
- HERC5 | c.1497G>T p.M499I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99987690; called by muse, mutect2, varscan2
- HNRNPH2 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99516343; called by muse, mutect2
- INSRR | c.2602C>T p.L868F | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.761); catalogued as COSV100947483; called by muse, mutect2
- ITGA6 | c.1153G>T p.E385* (on ENST00000442250; = p.E346* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99905493; called by muse, mutect2
- KCNH2 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.059); catalogued as COSV100059966; called by muse, mutect2, varscan2
- LSM2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100989549; called by muse, mutect2, varscan2
- LTBP2 | c.3204C>A p.N1068K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100000272; called by muse, mutect2, varscan2
- MELTF | c.1939G>T p.D647Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99586161; called by muse, mutect2, varscan2
- MEMO1 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99704153; called by muse, mutect2, varscan2
- MYBPC1 | c.544C>G p.Q182E (on ENST00000550270 / NM_206820.2; = p.Q207E on NM_002465.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.472); catalogued as COSV100637981; called by muse, mutect2, varscan2
- MYCBP2 | c.7502C>T p.S2501F (on ENST00000357337; = p.S2539F on NM_015057.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100630303; called by muse, mutect2
- MYO7B | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs375437795; called by muse, mutect2, varscan2
- NAALADL2 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101495293; called by muse, mutect2, varscan2
- NAMPT | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99747951; called by muse, mutect2
- NDFIP2 | c.341A>T p.N114I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs754913477, COSV99519255; called by muse, mutect2, varscan2
- NR4A2 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV59894500; called by muse, mutect2, varscan2
- NUB1 | c.1792G>A p.E598K (on ENST00000568733 / NM_001243351.1; = p.E584K on NM_016118.4) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100561281; called by muse, mutect2, varscan2
- OR13G1 | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100687244; called by muse, mutect2
- OR2T6 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs758848003, COSV100861532; called by muse, mutect2
- OR9Q2 | c.567T>A p.C189* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100285435; called by muse, mutect2
- PKHD1L1 | c.7846G>C p.V2616L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs756500652, COSV65747411; called by muse, mutect2, varscan2
- PLCD1 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99378790; called by muse, mutect2, varscan2
- POM121 | c.3451G>T p.A1151S (on ENST00000434423; = p.A886S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV99988306; called by muse, mutect2
- PSMD12 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV100635338; called by muse, mutect2, varscan2
- PTGDR | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs201541398, COSV100035572, COSV60094230; called by muse, mutect2, varscan2
- PTGFR | c.997T>A p.W333R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100882294; called by muse, mutect2, varscan2
- RANBP6 | c.2473G>T p.E825* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV99424144; called by muse, mutect2, varscan2
- RIN3 | c.2310C>G p.Y770* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99379172; called by muse, mutect2, varscan2
- SCN4A | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs370472562; called by muse, mutect2, varscan2
- SEPTIN6 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs756379839, COSV100595590; called by muse, mutect2, varscan2
- SNAP29 | c.582C>A p.H194Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV99300806; called by muse, mutect2, varscan2
- SPHK2 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709359; called by muse, mutect2, varscan2
- TENM4 | c.5277C>A p.S1759R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99574446; called by muse, mutect2
- TEP1 | c.2877C>A p.C959* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV99402366; called by muse, mutect2, varscan2
- TEX14 | c.883G>A p.E295K (on ENST00000240361 / NM_001201457.2; = p.E289K on NM_031272.5) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767891713, COSV99542200; called by muse, mutect2, varscan2
- TMEM132E | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs553628300, COSV100396269; called by muse, mutect2, varscan2
- TMPRSS6 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100695748; called by muse, mutect2, varscan2
- TRAF5 | c.1615A>G p.K539E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99807369; called by muse, mutect2, varscan2
- TRPC7 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV61452140; called by muse, mutect2
- UCN3 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100991704; called by muse, mutect2, varscan2
- UST | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.246); catalogued as COSV100819909; called by muse, mutect2
- WDR26 | c.1730G>C p.G577A (on ENST00000414423 / NM_001379403.1; = p.G477A on NM_025160.7) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99691219; called by muse, mutect2
- XKR6 | c.1841A>G p.Q614R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100440666, COSV58656211; called by muse, mutect2, varscan2
- ZCCHC8 | c.1514C>A p.T505K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV100288653; called by muse, mutect2, varscan2
- ZNF678 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100652754; called by muse, mutect2, varscan2
- CYTIP | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- KANK3 | c.1879del p.L627Cfs*43 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | called by mutect2, pindel, varscan2
- LARP4 | c.937_949del p.P313Tfs*32 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel
- LRP6 | c.3372_3379del p.R1125Kfs*3 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- TDRD1 | c.2522C>A p.S841Y | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- AGXT2 | c.1116G>A p.A372= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1207970057, COSV51485094; called by muse, mutect2, varscan2
- CACNA1F | c.5649C>G p.T1883= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV100544780, COSV59904999; called by muse, mutect2, varscan2
- CCP110 | c.714T>C p.Y238= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV101195271; called by muse, mutect2
- CSF2RB | c.2184C>T p.V728= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99453853; called by muse, mutect2, varscan2
- FRMD8 | c.1122G>A p.A374= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs745696102, COSV100454694; called by muse, mutect2, varscan2
- GPA33 | c.330T>A p.A110= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100901056; called by muse, mutect2
- IGKV2D-30 | c.192G>A p.R64= | Silent (SNP) | VAF 14/126 reads (11%) | called by mutect2, varscan2
- MAMLD1 | c.498C>A p.I166= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99475957; called by muse, mutect2, varscan2
- MISP | c.1827C>A p.P609= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99296806; called by muse, mutect2, varscan2
- NCAN | c.3180C>A p.T1060= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- OR5B3 | c.516C>T p.V172= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV100511982; called by muse, mutect2, varscan2
- PSMD4 | c.183G>A p.L61= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as rs151089424; called by muse, mutect2, varscan2
- TRPC7 | c.1524G>A p.Q508= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100725694; called by muse, mutect2, varscan2
- XPNPEP2 | c.1389C>T p.T463= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV100941479; called by muse, mutect2, varscan2
- ZAN | c.6735T>C p.A2245= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100769694; called by mutect2, varscan2
- SSPOP | n.1567C>T | RNA (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100022493; called by muse, mutect2
